CCDI case PBCITW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/767bce06-bd99-4e1a-b763-462d2ec3cf2e

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Germinoma: ICD-O-3 morphology code: 9064/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.7 years (6,472 days).

Biospecimens (3 samples)
- Sample 0DSZSG: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSZSH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSZSK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
